Somatic mutation profile of tumor specimen TCGA-UZ-A9PJ-01A (aliquot TCGA-UZ-A9PJ-01A-11D-A382-10) from TCGA case TCGA-UZ-A9PJ, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I.
Specimen TCGA-UZ-A9PJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 38a5fffc-3d2e-4b40-a95a-ee326bdb2579.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-UZ-A9PJ-10A (Blood Derived Normal), aliquot TCGA-UZ-A9PJ-10A-01D-A385-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7be00906-f1de-4a30-ab7c-9dea9f721018

The open-access MAF lists 60 somatic variants for this specimen: 42 protein-altering or splice-affecting, 17 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 37, Silent 17, Frame Shift Del 3, Splice Site 1, 5'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MET | c.3274G>A p.V1092I | Missense Mutation (SNP) | VAF 51/145 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs786202724, CM1210646, CM990852, COSV59257346; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACADM | c.638C>T p.A213V | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as COSV57714585; called by muse, mutect2, varscan2
- ACER1 | c.486G>C p.R162S | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.012); catalogued as COSV100034127; called by muse, mutect2, varscan2
- ACOT2 | c.479T>C p.V160A | Missense Mutation (SNP) | VAF 45/120 reads (38%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); catalogued as rs1192125137, COSV99469207; called by muse, mutect2, varscan2
- ADAMTS10 | c.2139C>G p.S713R | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.28); catalogued as COSV99547430; called by muse, mutect2, varscan2
- BCAR3 | c.521T>C p.F174S | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99551247; called by muse, varscan2
- CANX | c.116T>G p.I39S | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV99910677; called by muse, mutect2, varscan2
- CELSR2 | c.1982A>G p.Q661R | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99604707; called by muse, mutect2, varscan2
- CFAP410 | c.491T>C p.L164P | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (0.27); PolyPhen benign (0.184); catalogued as COSV100297213; called by muse, mutect2, varscan2
- CLIC4 | c.293T>C p.V98A | Missense Mutation (SNP) | VAF 71/154 reads (46%) | SIFT tolerated (0.17); PolyPhen benign (0.234); catalogued as rs779427717, COSV100978214; called by muse, mutect2, varscan2
- CTTNBP2NL | c.1643A>G p.H548R | Missense Mutation (SNP) | VAF 54/114 reads (47%) | SIFT tolerated (0.87); PolyPhen probably damaging (0.966); catalogued as COSV99600271; called by muse, mutect2, varscan2
- DHX9 | c.383G>A p.G128E | Missense Mutation (SNP) | VAF 113/208 reads (54%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV100841520; called by muse, mutect2, varscan2
- DNMT3A | c.2408+1G>T p.X803_splice | Splice Site (SNP) | VAF 34/68 reads (50%) | catalogued as COSV99264423; called by muse, mutect2, varscan2
- ERC2 | c.2674C>T p.R892W | Missense Mutation (SNP) | VAF 37/91 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs367719934, COSV55675922; called by muse, mutect2, varscan2
- GJA3 | c.1223C>T p.P408L | Missense Mutation (SNP) | VAF 49/97 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99576508; called by muse, mutect2, varscan2
- KAT8 | c.269A>G p.Y90C | Missense Mutation (SNP) | VAF 49/111 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54898644; called by muse, mutect2, varscan2
- KPNA1 | c.866T>A p.I289N | Missense Mutation (SNP) | VAF 103/226 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100724387; called by muse, varscan2
- KPNB1 | c.2351A>T p.H784L | Missense Mutation (SNP) | VAF 66/98 reads (67%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV99268399; called by muse, mutect2, varscan2
- LRRC36 | c.574A>G p.M192V | Missense Mutation (SNP) | VAF 41/83 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV99339119; called by muse, mutect2, varscan2
- MARCHF4 | c.910C>T p.R304W | Missense Mutation (SNP) | VAF 35/64 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1410905109, COSV56107808; called by muse, mutect2, varscan2
- MRPS22 | c.757_760del p.D253Nfs*22 (on ENST00000310776 / NM_001363893.1; = p.D254Nfs*22 on NM_020191.4) | Frame Shift Del (DEL) | VAF 24/53 reads (45%) | catalogued as rs868695898; called by mutect2, pindel, varscan2
- NLRP13 | c.1885G>A p.A629T | Missense Mutation (SNP) | VAF 93/171 reads (54%) | SIFT tolerated (0.19); PolyPhen benign (0.113); catalogued as COSV100738522; called by muse, mutect2, varscan2
- NUP205 | c.113T>G p.L38R | Missense Mutation (SNP) | VAF 151/493 reads (31%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV99607595; called by muse, mutect2, varscan2
- PCK1 | c.862T>C p.C288R | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100100949; called by muse, mutect2, varscan2
- PHF10 | c.894T>A p.D298E | Missense Mutation (SNP) | VAF 71/143 reads (50%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV100200118; called by muse, mutect2, varscan2
- POLB | c.578T>C p.V193A | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.011); catalogued as COSV99613477; called by muse, mutect2, varscan2
- POLN | c.2140A>C p.K714Q | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.374); catalogued as COSV101242783; called by muse, mutect2, varscan2
- RBM15B | c.2473G>T p.V825F | Missense Mutation (SNP) | VAF 38/81 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100082338; called by muse, mutect2, varscan2
- RBP5 | c.181T>C p.Y61H | Missense Mutation (SNP) | VAF 53/108 reads (49%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.749); catalogued as COSV99867688; called by muse, mutect2, varscan2
- RIDA | c.238A>G p.T80A | Missense Mutation (SNP) | VAF 38/64 reads (59%) | SIFT deleterious (0.01); PolyPhen benign (0.165); catalogued as COSV99645353; called by muse, mutect2, varscan2
- RIMS2 | c.1720G>A p.D574N (on ENST00000666250 / NM_001348490.2; = p.D382N on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 34/76 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765782930, COSV51652261, COSV99199638; called by muse, mutect2, varscan2
- RIN2 | c.1847A>G p.Y616C (on ENST00000255006 / NM_001242581.1; = p.Y567C on NM_018993.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 72/159 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99657893; called by muse, mutect2, varscan2
- SFSWAP | c.20G>A p.G7D | Missense Mutation (SNP) | VAF 32/64 reads (50%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.367); catalogued as rs768091766, COSV99906404; called by muse, varscan2
- SPATA20 | c.415G>A p.V139I (on ENST00000356488 / NM_001258372.1; = p.V155I on NM_022827.4) | Missense Mutation (SNP) | VAF 65/95 reads (68%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.847); catalogued as rs540627294, COSV99136697; called by muse, mutect2, varscan2
- TRMT44 | c.1573A>C p.K525Q | Missense Mutation (SNP) | VAF 65/131 reads (50%) | SIFT tolerated (0.5); PolyPhen benign (0.009); catalogued as COSV101077840; called by muse, mutect2, varscan2
- TRPC7 | c.2132T>C p.L711P | Missense Mutation (SNP) | VAF 58/123 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as COSV100726004; called by muse, mutect2, varscan2
- UPF1 | c.1097G>A p.R366Q (on ENST00000599848 / NM_001297549.2; = p.R355Q on NM_002911.4) | Missense Mutation (SNP) | VAF 44/87 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.215); catalogued as COSV99440398; called by muse, mutect2, varscan2
- ZFHX4 | c.9625G>A p.A3209T | Missense Mutation (SNP) | VAF 42/117 reads (36%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as COSV99267560; called by muse, mutect2, varscan2
- CELSR3 | c.1063_1076delinsT p.G355Sfs*2 | Frame Shift Del (DEL) | VAF 30/56 reads (54%) | called by pindel, varscan2*
- PBRM1 | c.1492del p.S498Afs*2 | Frame Shift Del (DEL) | VAF 13/33 reads (39%) | called by mutect2, pindel, varscan2
- RNF19A | c.600dup p.Y201Ifs*7 | Frame Shift Ins (INS) | VAF 34/95 reads (36%) | called by mutect2, pindel, varscan2
- SYNRG | c.10C>T p.R4W | Missense Mutation (SNP) | VAF 23/39 reads (59%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CDCA7 | c.684C>G p.R228= (on ENST00000347703 / NM_145810.3; = p.R307= on NM_031942.5) | Silent (SNP) | VAF 40/84 reads (48%) | catalogued as COSV100143761; called by muse, mutect2
- CRIP3 | c.267T>C p.P89= | Silent (SNP) | VAF 37/79 reads (47%) | catalogued as COSV99240581; called by muse, mutect2, varscan2
- FASTKD3 | c.660T>C p.I220= | Silent (SNP) | VAF 43/85 reads (51%) | catalogued as COSV99242106; called by muse, mutect2, varscan2
- GFPT2 | c.385C>T p.L129= | Silent (SNP) | VAF 42/88 reads (48%) | catalogued as COSV99518081; called by muse, mutect2, varscan2
- IGF2R | c.1986T>C p.N662= | Silent (SNP) | VAF 24/62 reads (39%) | catalogued as COSV100808168; called by muse, mutect2, varscan2
- INTS6 | c.780T>C p.P260= | Silent (SNP) | VAF 12/33 reads (36%) | catalogued as COSV100247264; called by muse, mutect2, varscan2
- IPO7 | c.225A>C p.P75= | Silent (SNP) | VAF 35/75 reads (47%) | catalogued as COSV101121851; called by muse, mutect2, varscan2
- MORC3 | c.2763A>G p.V921= | Silent (SNP) | VAF 33/69 reads (48%) | catalogued as COSV101265059; called by muse, mutect2, varscan2
- PLEKHG7 | c.69G>A p.S23= | Silent (SNP) | VAF 29/58 reads (50%) | catalogued as rs760574393, COSV67337764, COSV67337957; called by muse, mutect2, varscan2
- RABL6 | c.756C>T p.A252= | Silent (SNP) | VAF 66/145 reads (46%) | catalogued as COSV100273737; called by muse, mutect2, varscan2
- SMIM15 | c.129A>G p.K43= | Silent (SNP) | VAF 31/70 reads (44%) | catalogued as rs140323722; called by muse, mutect2, varscan2
- SON | c.5811A>T p.R1937= | Silent (SNP) | VAF 24/49 reads (49%) | catalogued as COSV99279796; called by muse, mutect2, varscan2
- SPDL1 | c.1230T>G p.L410= | Silent (SNP) | VAF 120/243 reads (49%) | catalogued as COSV99517766; called by muse, mutect2, varscan2
- SPIRE2 | c.675G>T p.P225= | Silent (SNP) | VAF 42/85 reads (49%) | catalogued as COSV100989011; called by muse, mutect2, varscan2
- STX17 | c.141C>A p.I47= | Silent (SNP) | VAF 33/62 reads (53%) | catalogued as COSV99408151; called by muse, mutect2, varscan2
- TANK | c.684A>G p.S228= | Silent (SNP) | VAF 93/186 reads (50%) | catalogued as rs762735018, COSV99376517; called by muse, mutect2, varscan2
- TTN | c.49185C>T p.V16395= (on ENST00000591111; = p.V8971= on NM_003319.4) | Silent (SNP) | VAF 26/55 reads (47%) | catalogued as COSV100629688; called by muse, mutect2, varscan2
- AFDN | chr6:167825963 del C | 5'Flank (DEL) | VAF 35/94 reads (37%) | called by mutect2, pindel, varscan2
